Gene-level copy-number profile of tumor specimen C3N-03880-01 (profiled together with C3N-03880-02) from CPTAC case C3N-03880, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 76.1 years (27,786 days).
Specimen C3N-03880-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 741c1148-9ed7-4c7a-9c1f-dc95f86dec7a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03880-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,716 have no estimate.
https://portal.gdc.cancer.gov/files/7c7e7fe0-3829-4e7a-922c-0fff473d706c

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 13; copy number 1: 152; copy number 2: 7,224; copy number 3: 20,781; copy number 4: 16,095; copy number 5: 7,842; copy number 6: 1,924; copy number 7: 2,653; copy number 8: 903; copy number 9: 578; copy number 10: 342; copy number 11: 46; copy number 12: 191; copy number 13: 139; copy number 16: 24.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–22,029,594, 1 gene (within-gene range 0–4): AL359922.1.
- chr9:21,892,188–21,995,301, 4 genes (within-gene range 0–4): AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,009,305, 2 genes (within-gene range 0–4): AL449423.1, CDKN2B.
- chr9:22,646,200–23,438,700, 4 genes: LINC01239, AL391117.1, CLIC4P1, AC017067.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 4,871 genes in 32 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:6,521,347–6,554,513, 1 gene, copy number 8 (within-gene range 3–8): NOL9.
- chr1:143,929,994–158,294,774, 633 genes, copy number 7 (broad region; genes not listed).
- chr2:102,619,553–103,623,830, 11 genes, copy number 8: SLC9A2, MFSD9, TMEM182, LINC01796, LINC01935, AC108051.1, AC073987.1, AC010881.1, CRLF3P1, AC018880.1, CAPZBP1.
- chr3:140,619,694–198,123,232, 984 genes, copy number 8–10 (broad region; genes not listed).
- chr4:76,114,659–76,898,144, 22 genes, copy number 8: NUP54, AC110795.1, SCARB2, FAM47E, AC034139.1, FAM47E-STBD1, STBD1, CCDC158, SNX5P1, RNU6-1000P, AC096743.2, AC096743.1, SHROOM3, AC112249.1, RNU6-145P, MIR4450, MIR548AH, SHROOM3-AS1, AC107072.1, AC104687.2, AC104687.1, SOWAHB.
- chr4:85,990,007–87,846,817, 34 genes, copy number 7 (within-gene range 4–7): MAPK10, MAPK10-AS1, RN7SKP96, MIR4452, PTPN13, SLC10A6, AC093827.1, C4orf36, AC093827.2, AC093827.5, AC093827.3, AC093827.4, AFF1, TECRP1, KLHL8, AC092658.1, GAPDHP60, AC108516.1, MIR5705, HSD17B13, AC108516.2, HSD17B11, RN7SL681P, AC112250.1, NUDT9, AC112250.2, SPARCL1, AC093895.1, DSPP, DMP1, Y_RNA, CHCHD2P7, IBSP, MEPE.
- chr4:105,137,280–105,708,093, 13 genes, copy number 7 (within-gene range 3–7): AC004069.1, TET2, TET2-AS1, RN7SL89P, PPA2, RNU6-553P, EEF1A1P9, PIMREGP2, ATP5F1EP1, AC004066.1, ARHGEF38, ARHGEF38-IT1, AC105391.1.
- chr4:107,824,563–117,085,576, 135 genes, copy number 7 (broad region; genes not listed).
- chr6:36,243,203–58,438,364, 430 genes, copy number 9–11 (within-gene range 4–11) (broad region; genes not listed).
- chr8:31,639,222–32,855,666, 3 genes, copy number 9 (within-gene range 4–14): NRG1, AC068931.1, NRG1-IT1.
- chr8:32,256,496–33,227,147, 9 genes, copy number 9 (within-gene range 9–14): RNA5SP263, NRG1-IT3, AC083977.1, RNU6-663P, AC090204.1, MTND1P6, MTND2P32, RANP9, AC104027.1.
- chr8:37,095,150–37,095,390, 1 gene, copy number 10: SMARCE1P4.
- chr8:38,223,957–38,973,912, 21 genes, copy number 16 (within-gene range 4–16): AC084024.4, DDHD2, PLPP5, NSD3, AC087362.2, AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22, C8orf86, AC069120.1, RNF5P1, AC016813.1, TACC1, Y_RNA, AC067817.1, AC067817.2, PLEKHA2.
- chr8:39,106,990–41,625,001, 41 genes, copy number 7–12: ADAM32, RPL3P10, AC105185.1, ADAM5, ADAM3A, AC123767.1, ADAM18, ADAM2, AP005902.2, AP005902.1, IDO1, AC007991.3, AC007991.2, AC007991.4, IDO2, AC007991.1, AC087518.1, LINC02866, TCIM, AC022733.1, SIRLNT, AC105999.1, AC010857.1, ZMAT4, AC048387.1, RNU6-356P, SFRP1, MIR548AO, RPS29P2, AC104393.1, RNU6-895P, SNORD65B, AC016868.1, GOLGA7, AC009630.1, KRT18P37, GINS4, AC009630.2, AC009630.4, GPAT4, AC009630.3.
- chr8:46,028,804–46,028,892, 1 gene, copy number 9: AC118650.1.
- chr9:64,637,845–64,709,311, 2 genes, copy number 11: AL445665.1, BMS1P11.
- chr10:62,339,553–62,375,166, 1 gene, copy number 7 (within-gene range 5–7): AC024597.1.
- chr10:62,374,192–71,077,810, 138 genes, copy number 7 (broad region; genes not listed).
- chr11:47,905,323–50,361,706, 78 genes, copy number 7 (broad region; genes not listed).
- chr11:58,834,065–59,566,283, 35 genes, copy number 8: GLYATL2, GLYATL1P2, GLYATL1, AP001652.1, AP001636.3, AP001636.2, GLYATL1P1, AP001636.1, GLYATL1P4, GLYATL1B, FAM111B, FAM111A-DT, AP001258.1, FAM111A, DTX4, MPEG1, RN7SL42P, WARS1P1, SLC25A47P1, AP002358.1, AP002358.2, RN7SL435P, OR5AN2P, OR5BR1P, OR5AN1, OR5BB1P, OR5A2, OR5A1, OR4D6, OR4D10, OR4D8P, OR4D11, OR4D9, OR4D7P, LINC02739.
- chr11:70,078,302–73,598,189, 124 genes, copy number 8–12 (within-gene range 4–12) (broad region; genes not listed).
- chr12:41,188,320–42,459,715, 20 genes, copy number 7 (within-gene range 5–7): PDZRN4, AC090531.1, RNA5SP360, MTND2P17, MTND1P24, LINC02400, AC090630.1, AC006197.1, AC023513.1, GXYLT1, YAF2, PPHLN1, AC020629.1, ZCRB1, MIR7851, SNORA74, AC079684.1, RNU6-249P, AC079601.2, Y_RNA.
- chr12:42,459,366–42,466,128, 1 gene, copy number 7 (within-gene range 5–7): AC079601.1.
- chr13:57,991,350–59,263,391, 10 genes, copy number 8: RNA5SP30, LINC02338, LINC00374, AL161423.1, RNY4P29, CTAGE16P, DNAJA1P1, HMGN2P39, POLR3KP1, RPP40P2.
- chr14:24,809,656–31,861,224, 89 genes, copy number 7–8 (broad region; genes not listed).
- chr14:32,329,298–32,837,684, 1 gene, copy number 8 (within-gene range 3–8): AKAP6.
- chr14:32,879,246–41,904,549, 133 genes, copy number 8 (broad region; genes not listed).
- chr17:45,894,551–46,028,334, 1 gene, copy number 10 (within-gene range 5–10): MAPT.
- chr17:45,999,250–54,478,168, 260 genes, copy number 7–10 (broad region; genes not listed).
- chr17:61,865,367–82,945,914, 691 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr18:22,586,465–40,144,504, 237 genes, copy number 10–13 (broad region; genes not listed).
- chr19:27,638,483–45,038,198, 711 genes, copy number 7–12 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 149. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
